Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3U8, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3U8-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

CC:

Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

Specimens Submitted:

1: Left spermatic cord with liposarcoma and left testis

DIAGNOSIS:

1. Left spermatic cord and left testis; radical orchiectomy:
- High grade leiomyosarcoma with spindle and epithelioid features involving spermatic cord.
- Tumor is seen as two nodules, 4.5 x 3.5 x 2.0cm, and 3.5 x 2.8 x 1.5cm.
- Tumor wraps around spermatic cord and involves adipose tissue and skeletal muscle.
- There is 15% gross necrosis.
- Mitoses: 20 mitoses per 50 high power fields.
- Vascular invasion is present.
- The spermatic cord margin is free of tumor. Tumor is seen within 1mm of soft tissue margin of resection.
- Unremarkable testis with preserved spermatogenesis.
- Skin with scar.
- One benign lymph node (0/1).

NOTE: Immunohistochemical stains show that the tumor is positive for desmin, SMA and rare CDK4 and MDM2 positive cells (nuclear staining). The tumor is negative for myogenin. Even though rare positivity for CDK4 and MDM2 is seen no obvious well-differentiated liposarcoma component is seen. A primary leiomyosarcoma is favored.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

ICD-0-3

leiomyosarcoma, NOS 8890/3

Path Site: spermatic cord C63.1

CQCF Site: retroperitoneum C48.0

hw
9/11/12

[page 2 of 2]
SURGICAL

Page 2 of 2

1. The specimen is received fresh, labeled "left spermatic cord with liposarcoma and left testis" and consists of a testis (5.0 x 3.0 x 2.2cm), attached spermatic cord (13 x 1.2cm), adjacent soft tissue and ellipse of skin (9.0 x 1.1cm) with a well-healed scar (7.2cm). The external surface is inked black. On cut section, two discrete, well-circumscribed nodules with similar cut surfaces are seen adjacent to the spermatic cord. These nodules (T1, 4.5 x 3.5 x 2.0cm, and T2, 2.8 x 3.5 x 1.5cm) have a fleshy, tan consistency with central hemorrhage and approximately 15% central tumoral necrosis. It appears to be 0.1cm from the closest inked surface. The testis is unremarkable, and the cut section does not show any gross abnormalities. There is a separate tan nodule within the adipose tissue, 0.8 x 0.6 x 0.5cm in dimension (?lymph node). The relationships to the margin are as follows: 3.8cm from the spermatic cord margin; 0.1cm from the closest adipose (black-inked) surface. Photographs and TPS are taken.

Summary of sections:

SCM - spermatic cord margin, en face
T1 - representative sections of nodule #1.
T2 - representative sections nodule #2
T12 - tissue between nodules #1 and #2
N nodule in adipose tissue
SCP - additional sections of spermatic cord (proximal)
SCD spermatic cord, distal
TE - unremarkable testis.
S skin with scar

Summary of Sections:

Part 1: Left spermatic cord with liposarcoma and left testis

Block	Sect.	Site	PCs
1		N	2
1		S	1
1		SCD	1
1		SCM	1
1		SCP	1
5		T1	5
1		T12	1
4		T2	4
1		TE	1

** End of Report **

Source: NCI Genomic Data Commons file fb88e543-b23d-45e1-ac0b-bec77a44c55c (TCGA-DX-A3U8.FE8F8597-3F21-4A5F-AE07-F6EA54F889EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).